TARGET case TARGET-40-NAAGKH — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/72c616e2-1cdc-5fbc-b060-c1c434427818

Demographics
Sex at birth: male; Race: asian; Age at index: 19 years; Vital status: Dead; Days to death: 514 days (1.4 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 19.7 years (7,180 days); Year of diagnosis: 2004; Metastasis at diagnosis: No Metastasis; Days to last follow up: 514 days (1.4 years).
   Pathology details: Necrosis percent: 80.

Follow-up (2 entries)
- Days to follow up: 293 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 293 days; Days to first event: 293 days; First event: Relapse.
- Days to follow up: 514 days (1.4 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2006.

Biospecimens (1 sample)
- Sample TARGET-40-NAAGKH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAGKH-01A-01D:
- Specimen Type: tumor DNA

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 514
- Protocol: Other osteosarcoma
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Tibia
- Specific tumor region: Proximal
- Definitive Surgery: Limb sparing
- Primary site progression: Yes
- Site of initial relapse: Lung
- Time to first enrollment on relapse protocol in days: 307
